Gene-level copy-number profile of tumor specimen C3N-03009-01 (profiled together with C3N-03009-03) from CPTAC case C3N-03009, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.9 years (21,529 days).
Specimen C3N-03009-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 42079f9c-d1fc-4cbb-ae4c-da62b4ee188c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03009-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/400842b2-08ce-40ac-abda-d7b50aba751e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 534; copy number 1: 1,492; copy number 2: 14,858; copy number 3: 21,486; copy number 4: 16,164; copy number 5: 4,016; copy number 6: 257; copy number 7: 3; copy number 8: 5; copy number 9: 21; copy number 15: 3; copy number 16: 24; copy number 29: 7; copy number 92: 6; copy number 105: 2; copy number 156: 3.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:54,057,690–55,074,557, 6 genes: AC115282.1, CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–4): CDKN2A-DT.
- chr9:24,542,952–24,545,946, 1 gene: IZUMO3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 74 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:99,948,295–100,903,282, 24 genes, copy number 9–15: CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P.
- chr12:67,265,842–68,850,686, 42 genes, copy number 16–156 (within-gene range 4–156): GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr13:73,054,976–73,113,018, 3 genes, copy number 7: KLF5, FABP5P1, RNU6-66P.
- chr19:43,192,702–43,269,530, 3 genes, copy number 8: PSG4, CEACAMP10, PSG9.
- chr22:18,361,820–18,391,105, 2 genes, copy number 8: FAM230J, AC011718.1.

Autosomal genes at a single copy (total copy number 1): 91. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
